Gene-level copy-number profile of tumor specimen TCGA-05-4417-01A from TCGA case TCGA-05-4417, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 51.4 years (18,780 days).
Specimen TCGA-05-4417-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.6771edd5-a412-4d85-bc5e-7ba862721a43.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-05-4417-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/59cf326d-7aa9-4c8f-8833-b6402fac2263

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 777; copy number 2: 20,215; copy number 3: 19,412; copy number 4: 13,217; copy number 5: 3,563; copy number 6: 2,147; copy number 7: 150; copy number 8: 252; copy number 9: 65; copy number 15: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-05-4417-01A-22D-1854-01): tumor purity 0.4, ploidy 2.93, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 488 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:25,747,433–27,985,063, 21 genes, copy number 15 (within-gene range 2–15): SEL1L3, AC092436.3, SMIM20, AC133961.1, LINC02357, AC097714.1, RBPJ, CCKAR, TBC1D19, AC107390.1, STIM2, STIM2-AS1, PIMREGP4, AC024132.2, AC024132.1, LINC02261, Y_RNA, AC024132.3, IGBP1P5, AC007106.2, AC007106.1.
- chr4:31,171,013–43,598,844, 161 genes, copy number 7–8 (broad region; genes not listed).
- chr14:22,066,016–22,506,702, 65 genes, copy number 9 (broad region; genes not listed).
- chr14:24,809,656–42,268,586, 241 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 777. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
